Surgical pathology report (de-identified scan), TCGA case TCGA-5P-A9JZ, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University Hospital Erlangen, specimen TCGA-5P-A9JZ-01A (Primary Tumor).

ICD-O-3

Carcinoma, papillary renal cell

8260/3

Site: R Kidney No. 64.9

7/5 6/18/14

1. Peri-renal fat layer is free of tumor
2. One 4.2 cm in diameter Papillary Renal Cell Carcinoma, Type I without mayor infiltration of lymphnodes , with minimal diffusion to the surgical border of 0.6 cm.

pTNM classification version 2002: Malignant Tumor

Stage: pT1b, R0

Grade: GII

ICD-O-Code: 8260/3

Laterality = (R)

Source: NCI Genomic Data Commons file 8b098d24-0a60-42fe-be15-6cb4cdca60a6 (TCGA-5P-A9JZ.5E01A3C9-BFCC-4C36-ADA7-43902EFD8A24.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).